MMRF case MMRF_1786 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b7a0a4ed-f438-4b75-a1fa-80bc17e06b73

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.1 years (17,585 days); ISS stage: I; Days to last known disease status: 1,087 days (3.0 years); Days to last follow up: 1,087 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 109 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 120 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 207 days; Days to treatment end: 360 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 360 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 46.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.732 mg/dL; Immunoglobulin G 38.2 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 9.9 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 100 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.275 mg/dL; Hemoglobin 7.01 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 8.1 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.7 g/dL; Glucose 6.33 mmol/L.
- Day 185 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.843 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 5.61 mmol/L.
- Day 276 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 4.29 mmol/L.
- Day 360 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.458 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 0.401 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.78 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 5.45 mmol/L.
- Day 422 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 0.354 g/L; Immunoglobulin M 0.318 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.9 g/dL; Glucose 4.51 mmol/L.
- Day 549 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.664 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 0.273 g/L; Immunoglobulin M 0.298 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.
- Day 633 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.893 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 0.359 g/L; Immunoglobulin M 0.264 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 710 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 19.7 g/L; Immunoglobulin A 0.383 g/L; Immunoglobulin M 0.277 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 5.01 mmol/L.
- Day 822 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 0.453 g/L; Immunoglobulin M 0.238 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 6.82 mmol/L.
- Day 913 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.554 g/L; Immunoglobulin M 0.254 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.95 mmol/L.
- Day 970 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.978 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 0.597 g/L; Immunoglobulin M 0.289 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.56 mmol/L.
- Day 1,087 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 19.4 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.426 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.9 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 8.5 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -3: Weight: 74 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1786_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1786_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
- Sample MMRF_1786_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 185 days.
